Somatic mutation profile of tumor specimen TCGA-A7-A5ZW-01A (aliquot TCGA-A7-A5ZW-01A-12D-A29N-09) from TCGA case TCGA-A7-A5ZW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 48.0 years (17,529 days).
Specimen TCGA-A7-A5ZW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15dd4e19-bdef-4303-9511-10fd35871b5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A5ZW-10A (Blood Derived Normal), aliquot TCGA-A7-A5ZW-10A-01D-A29N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d49d84d-33ca-415e-b828-0e8d452d7b5c

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 16, Silent 5, Frame Shift Ins 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC025165.3 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.3); catalogued as rs945701014, COSV55744279; called by muse, mutect2, varscan2
- AKAP9 | c.9292G>C p.E3098Q (on ENST00000359028; = p.E3074Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.116); catalogued as COSV62346994; called by muse, mutect2
- ALOX5AP | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV66857955; called by muse, mutect2, varscan2
- ANKRD11 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV56361501; called by muse, mutect2, varscan2
- DHX9 | c.1531G>T p.D511Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62359777; called by muse, mutect2, varscan2
- DTX1 | c.1715C>A p.S572* | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | catalogued as rs144113606, COSV55656224; called by muse, mutect2, varscan2
- EPB41L3 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV59454412, COSV59467029; called by muse, mutect2, varscan2
- HDAC1 | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV65191080; called by muse, mutect2, varscan2
- HMGCLL1 | c.512T>C p.V171A | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99231235; called by muse, mutect2
- IFT80 | c.1078A>G p.T360A | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100424287; called by muse, mutect2
- KCNA7 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as COSV55503462; called by muse, mutect2, varscan2
- KMT2C | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51442516, COSV51492081; called by muse, mutect2, varscan2
- METTL18 | c.394G>T p.V132L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV53679042, COSV99609587; called by muse, mutect2, varscan2
- SOAT2 | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV56857374; called by muse, mutect2, varscan2
- WDR93 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs369409113; called by muse, mutect2, varscan2
- IGHV3-64 | c.62A>G p.E21G | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- KDR | c.3503dup p.Q1169Sfs*41 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.3772del p.Y1258Ifs*11 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- FAT1 | c.9105C>T p.D3035= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs759140245, COSV71674258, COSV71674302; called by muse, mutect2, varscan2
- HDLBP | c.3393C>T p.D1131= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs780186842, COSV60496008; called by muse, mutect2, varscan2
- MICAL3 | c.1806C>T p.A602= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV52897384; called by muse, mutect2, varscan2
- MTARC1 | c.378C>A p.L126= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV65055703; called by muse, mutect2, varscan2
- PCDHA9 | c.1353C>T p.N451= | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as rs1554143388, COSV65324575; called by muse, mutect2, varscan2
